Somatic mutation profile of tumor specimen TCGA-CS-4938-01B (aliquot TCGA-CS-4938-01B-11D-1893-08) from TCGA case TCGA-CS-4938, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 31.5 years (11,509 days).
Specimen TCGA-CS-4938-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40c2cc48-9a2c-4196-8b56-005fbf7057fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-4938-10A (Blood Derived Normal), aliquot TCGA-CS-4938-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5291903-0423-4cc6-a1a3-7703c5a3df94

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 11, Silent 5, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/78 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 84/104 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTRT1 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64418903; called by muse, mutect2, varscan2
- ADAM22 | c.719A>G p.Y240C | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1408187357, COSV55979111; called by muse, mutect2
- C3 | c.3550C>T p.Q1184* | Nonsense Mutation (SNP) | VAF 22/144 reads (15%) | catalogued as COSV55574520; called by muse, mutect2, varscan2
- ENPEP | c.1634C>G p.P545R | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54452318; called by muse, mutect2, varscan2
- FGF5 | c.613C>G p.R205G | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56890489, COSV56891798; called by muse, mutect2, varscan2
- KDM7A | c.952A>C p.S318R | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV50092191; called by muse, mutect2, varscan2
- P3H2 | c.991G>T p.A331S | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV60022727; called by muse, mutect2, varscan2
- TKTL2 | c.928C>G p.P310A | Missense Mutation (SNP) | VAF 15/259 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV54919495; called by muse, mutect2
- TPO | c.2134G>A p.G712S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.096); catalogued as rs1331129490, COSV61103461; called by muse, mutect2
- ATRX | c.1074del p.K358Nfs*2 | Frame Shift Del (DEL) | VAF 96/259 reads (37%) | called by mutect2, pindel, varscan2
- ATRX | c.1073A>G p.K358R | Missense Mutation (SNP) | VAF 100/228 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- ADAD1 | c.1332A>T p.P444= | Silent (SNP) | VAF 69/181 reads (38%) | catalogued as COSV56644138; called by muse, mutect2, varscan2
- CELF6 | c.324C>T p.H108= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as rs140371170; called by muse, varscan2
- KLK10 | c.609C>T p.V203= | Silent (SNP) | VAF 124/370 reads (34%) | catalogued as COSV59398452; called by muse, mutect2, varscan2
- TTLL7 | c.2322A>G p.L774= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as COSV53085210; called by muse, mutect2, varscan2
- ZNF185 | c.15T>C p.A5= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV59276454; called by muse, mutect2, varscan2
